Surgical pathology report (de-identified scan), TCGA case TCGA-H6-8124, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-H6-8124-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Head of pancreas and duodenum, resection:

Moderately to poorly differentiated invasive pancreatic adenocarcinoma, ductal type.

Note: The margins of resection are negative for malignancy.
Metastatic carcinoma is present in 2 of 9 peripancreatic lymph nodes.

B. Gallbladder, resection: Subacute and chronic cholecystitis

Microscopic Description:

A.

Histologic type: Pancreatic adenocarcinoma, ductal type

Tumor size: 3 cm

Tumor location: Head of pancreas, 4.5 cm from gross pancreatic margin

Tumor grade: 2-3 of 3

Perineural invasion: Present

Vascular invasion: Focally compatible with lymphatic invasion

Uncinate margin: Negative for malignancy

Pancreatic margin: Negative for malignancy.

Lymph nodes: Metastatic carcinoma is present in 2 of 9 peripancreatic lymph nodes. The largest metastasis is 1 mm in greatest dimension.

Duodenum: Unremarkable

Uninvolved pancreas: Chronic pancreatitis with atrophy and fibrosis

pTNM stage: T3 N1

Other findings: The tumor focally invades up to a peripancreatic lymph node in block A3, so I consider it not "limited to the pancreas"

B. Microscopic examination performed.

Specimen

A. Head of pancreas duodenum bile duct stitch short uncinate long neck pancreas

B. Gallbladder

Clinical Information

Mass head of pancreas

Intraoperative Consultation

Head of pancreas and duodenum, resection: Ductal carcinoma of pancreas. Margins negative for malignancy.

[page 2 of 2]
Gross Description

The specimen is received unfixed head of pancreas duodenum and bile duct so duodenal and head of pancreas resection specimen. The duodenal portion the specimen measures 25 cm in length and up to 4.5 cm in diameter are the pancreatic portion the specimen measures 6.5 by 2.5 by 5 cm. There are sutures on the specimen. A long suture is on the pancreatic resection margin where there are staples. The short suture is in the uncinate margin. The pancreatic margin is inked blue the uncinate margin is inked red the duodenal mucosa is edematous over the head of the pancreas but is otherwise unremarkable. On cut section there is a white sclerotic mass that is 3 cm in diameter in the head of the pancreas and appears to be 4.5 cm from the pancreatic margin. The margins and the tumor are taken for frozen section diagnosis. A portion of tumor and pancreas are taken for research purposes. Sections after fixation.

Block summary: 1,2 duodenal margins of resection; 3-6 tumor head of pancreas; 7 peripancreatic lymph nodes; 8 ampulla of Vater; 9-13 more distal pancreas; 14-18 peripancreatic lymph nodes.

Specimen B. is received unfixed labeled gallbladder and consists of a pink and green gallbladder measuring 8 by 4 by 1 cm. Gallbladder contains abundant green viscous. No gallstones are seen. The wall of the gallbladder 0.2 cm in thickness. The mucosal surface is tan to green. Sections after fixation. RS2

Source: NCI Genomic Data Commons file a1e75bd7-a7c0-4d78-9941-55aa81e1af48 (TCGA-H6-8124.50AC30F1-6158-491C-B7AF-20E64FD435BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).